TCGA case TCGA-C5-A7X3 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4ed1616e-8c62-4104-bcbe-26d7059f04d0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 70 years; Vital status: Dead; Days to death: 284 days.

Diagnoses (1)
1. Squamous cell carcinoma, large cell, nonkeratinizing, NOS: ICD-O-3 morphology code: 8072/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 70.3 years (25,665 days); Year of diagnosis: 1997; Method of diagnosis: Biopsy; FIGO stage: Stage IIIB; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Amifostine; Days to treatment start: 5 days; Days to treatment end: 16 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Fluorouracil; Days to treatment start: 5 days; Days to treatment end: 26 days; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 5 days; Days to treatment end: 62 days; Treatment dose: 3,060 cGy; Number of fractions: 17; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, Internal; Days to treatment start: 26 days; Days to treatment end: 48 days; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil; Treatment intent type: Adjuvant; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Treatment dose: 3,060 cGy; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment anatomic sites: Pelvis.

Follow-up (1 entry)
- Days to follow up: 284 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Never Used.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 79 kg; Height: 160 cm; BMI: 30.9.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A7X3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-C5-A7X3-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 39; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 5.
- Sample TCGA-C5-A7X3-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A7X3-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 7; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 7; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); New tumor event diagnosis indicator: No.
- Treatment, Radiation therapy info: Brachytherapy type: HDR; Radiation therapy xrt type: External beam radiation.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment 2: Chemo concurrent type other: 5 fu RTOG protocol.
- Drug treatment 1: Pharmaceutical therapy drug name: Cisplatinum; Clinical trial drug classification: Cisplatinum.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-flurouracil; Clinical trial drug classification: 5-flurouracil.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 284 days; disease-specific survival: no event (censored), 284 days; progression-free interval: no event (censored), 284 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A7X3-01A-11D-A350-01): tumor purity 0.22, ploidy 3.57, whole-genome doublings 1.
